Somatic mutation profile of tumor specimen TCGA-HC-A6AP-01A (aliquot TCGA-HC-A6AP-01A-11D-A30E-08) from TCGA case TCGA-HC-A6AP, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.1 years (22,318 days).
Specimen TCGA-HC-A6AP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81494f8b-39d4-4956-8a71-a8ffc2f7c5f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A6AP-10A (Blood Derived Normal), aliquot TCGA-HC-A6AP-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12d4240d-f98a-4d19-aab2-0c51cc8df770

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 16, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 28/181 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as rs193921065, COSV61652814, COSV61652918; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ALX1 | c.300C>A p.N100K | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.034); catalogued as COSV57492870; called by muse, mutect2, varscan2
- CD8B | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58926684; called by muse, mutect2
- DPH1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1300818097, COSV53984941; called by muse, mutect2
- ENPP5 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV57909154; called by muse, mutect2, varscan2
- EPB41L3 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs141321874; called by muse, mutect2, varscan2
- HERC1 | c.1550C>G p.S517* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV71248559; called by muse, mutect2, varscan2
- HERC1 | c.1549T>C p.S517P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71248562; called by muse, mutect2, varscan2
- ICE1 | c.3272C>G p.P1091R | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs1390011273, COSV56827698; called by muse, mutect2
- ODAM | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 41/263 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV101258049, COSV68573040; called by muse, mutect2, varscan2
- RREB1 | c.2279A>G p.E760G | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV58560050; called by muse, mutect2
- SCN10A | c.3995G>A p.C1332Y | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71861889; called by muse, mutect2
- SEC24D | c.2182A>C p.T728P | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54881181; called by muse, mutect2, varscan2
- SNW1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.814); catalogued as COSV55054994; called by muse, varscan2
- SORCS1 | c.2168G>T p.C723F | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53877171; called by muse, mutect2, varscan2
- TP63 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53210273; called by muse, mutect2, varscan2
- TTN | c.98287T>C p.S32763P (on ENST00000591111; = p.S25339P on NM_003319.4) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | PolyPhen possibly damaging (0.663); catalogued as COSV60150911; called by muse, mutect2, varscan2
- ALDH1L1 | c.1768_1769insT p.A590Vfs*35 | Frame Shift Ins (INS) | VAF 20/126 reads (16%) | called by mutect2, pindel*, varscan2
- CLVS2 | c.219G>A p.A73= | Silent (SNP) | VAF 38/215 reads (18%) | catalogued as rs1489825389, COSV51561606; called by muse, mutect2, varscan2
- NOX4 | c.543A>C p.A181= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV54456321; called by muse, mutect2, varscan2
